Somatic mutation profile of tumor specimen MP2PRT-PASSFZ-TBP1-A (aliquot MP2PRT-PASSFZ-TBP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASSFZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,147 days).
Specimen MP2PRT-PASSFZ-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a252f2e-4ae8-41c4-a9f5-87e57ff4a0e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASSFZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASSFZ-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/887aa095-386d-4943-af70-a52ce0843237

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ENSA | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 31/522 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV55026128; called by muse, mutect2
- FLT3 | c.1471G>C p.V491L | Missense Mutation (SNP) | VAF 121/363 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV54042664, COSV54046758; called by muse, mutect2, varscan2
- PGAP4 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 41/382 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.193); catalogued as rs575803870; called by muse, mutect2, varscan2
- TENM3 | c.4214C>A p.A1405D | Missense Mutation (SNP) | VAF 140/530 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV69301205; called by muse, mutect2, varscan2
- FAM171B | c.2134A>T p.N712Y | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- HTR2C | c.230C>A p.A77E | Missense Mutation (SNP) | VAF 185/686 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC71 | c.98C>A p.A33E | Missense Mutation (SNP) | VAF 179/555 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SOX4 | c.746C>A p.P249H | Missense Mutation (SNP) | VAF 41/1075 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); called by muse, mutect2
- STX16 | c.365T>C p.I122T (on ENST00000371141 / NM_001001433.3; = p.I101T on NM_003763.6) | Missense Mutation (SNP) | VAF 29/404 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IL20RA | c.1401G>A p.S467= | Silent (SNP) | VAF 18/659 reads (3%) | catalogued as rs1222429841; called by muse, mutect2
- PCDHA10 | c.1698G>A p.A566= | Silent (SNP) | VAF 21/492 reads (4%) | catalogued as COSV56486635; called by muse, mutect2
- RNF17 | c.802T>C p.L268= | Silent (SNP) | VAF 63/162 reads (39%) | called by muse, mutect2, varscan2
- ZNF146 | c.471A>G p.K157= | Silent (SNP) | VAF 15/311 reads (5%) | catalogued as rs1342456459; called by muse, mutect2
